Somatic mutation profile of tumor specimen TCGA-CQ-5329-01A (aliquot TCGA-CQ-5329-01A-01D-1683-08) from TCGA case TCGA-CQ-5329, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.6 years (17,028 days).
Specimen TCGA-CQ-5329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66d5aa0b-0db8-4cb5-a5f3-471c3027c87c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5329-10A (Blood Derived Normal), aliquot TCGA-CQ-5329-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39073cc2-981d-481d-9189-c6ec3169eefb

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100896972; called by muse, mutect2, varscan2
- ADGRE1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV99165528; called by muse, mutect2, varscan2
- CCDC38 | c.731C>A p.S244* | Nonsense Mutation (SNP) | VAF 50/139 reads (36%) | catalogued as COSV100717749; called by muse, mutect2, varscan2
- DCC | c.2031C>A p.N677K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs1344090865, COSV100501621; called by muse, mutect2, varscan2
- FAM234A | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV100056165; called by muse, mutect2, varscan2
- FILIP1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs776854335, COSV52727783; called by muse, mutect2, varscan2
- KCNA4 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069112; called by muse, mutect2, varscan2
- KCNK17 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs566450809, COSV100950249; called by muse, mutect2, varscan2
- KRT85 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs141072357; called by muse, mutect2, varscan2
- NALCN | c.2524C>T p.R842* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs779930597, COSV51922520; called by muse, mutect2, varscan2
- NOTCH1 | c.6067G>A p.A2023T | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181025067, COSV53097791; called by muse, mutect2, varscan2
- NYAP2 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746005558, COSV55998011, COSV56014816; called by muse, mutect2, varscan2
- OR3A2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV101375065; called by muse, mutect2, varscan2
- OR52N1 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV100398700; called by muse, mutect2, varscan2
- PCDHGA5 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53952790, COSV99542390; called by muse, mutect2, varscan2
- PLPPR1 | c.385+2T>A p.X129_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100883411; called by muse, mutect2, varscan2
- PRSS1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs768255958, COSV61191955; called by muse, mutect2
- SERPINF1 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266103725, COSV99628901; called by muse, mutect2, varscan2
- SIDT2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV99638095; called by muse, mutect2, varscan2
- TJAP1 | c.560G>A p.R187Q (on ENST00000372445 / NM_001146016.1; = p.R177Q on NM_080604.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1416928654, COSV99447026; called by muse, mutect2, varscan2
- ZNF512 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs767038845, COSV100820886; called by muse, mutect2, varscan2
- MAGEF1 | c.627_631del p.Y209* | Nonsense Mutation (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- SORL1 | c.3444T>G p.S1148R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP2A3 | c.945C>T p.I315= | Silent (SNP) | VAF 59/91 reads (65%) | catalogued as COSV99989430; called by muse, mutect2, varscan2
- DVL2 | c.996C>T p.D332= | Silent (SNP) | VAF 50/73 reads (68%) | catalogued as rs141544993; called by muse, mutect2, varscan2
- FNDC1 | c.1836G>A p.A612= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV51937145; called by muse, mutect2, varscan2
- GSAP | c.1221G>T p.L407= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV57529593, COSV99990358; called by muse, mutect2, varscan2
- MICAL2 | c.2997C>T p.S999= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs774375661, COSV56325348; called by muse, mutect2, varscan2
- PDHA2 | c.93C>T p.D31= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs143281239, COSV54779791; called by muse, mutect2, varscan2
